Somatic mutation profile of tumor specimen 0DN3SR from CCDI case PBCAYB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.4 years (3,794 days).
Specimen 0DN3SR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 767220ec-1f96-410c-bf47-f7bd5d45e0d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN3R3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abbc515e-90ce-45a1-a625-1caf89b54bb1

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDS | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs199565117, COSV99981121; called by muse, varscan2
- ZNF777 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 226/646 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs571183325, COSV56099912; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/251 reads (10%) | called by muse, varscan2
- TIGIT | chr3:114294026 C>A | 5'Flank (SNP) | VAF 32/124 reads (26%) | called by muse, varscan2
